Somatic mutation profile of tumor specimen TCGA-D3-A3CE-06A (aliquot TCGA-D3-A3CE-06A-11D-A19A-08) from TCGA case TCGA-D3-A3CE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.8 years (28,782 days).
Specimen TCGA-D3-A3CE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76f17664-d37a-45fb-8e1b-f088727a7e87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3CE-10A (Blood Derived Normal), aliquot TCGA-D3-A3CE-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/647286d8-8fd2-4963-806a-3483c5da168e

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/95 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADA2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs1285480967, COSV52830695; called by muse, mutect2, varscan2
- ARMCX5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV55766097; called by muse, mutect2, varscan2
- BTN3A2 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as rs776878011, COSV62686924; called by mutect2, varscan2
- C17orf80 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52145343; called by muse, mutect2, varscan2
- CKAP2L | c.231A>C p.K77N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV56695967; called by muse, varscan2
- DOCK11 | c.3347T>C p.V1116A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as COSV52235524; called by muse, mutect2, varscan2
- DYNC2LI1 | c.490A>G p.M164V | Missense Mutation (SNP) | VAF 123/456 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53182642; called by muse, mutect2, varscan2
- FOCAD | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620586; called by muse, varscan2
- GPM6A | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54550058; called by muse, mutect2, varscan2
- GRIA3 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV52052616; called by muse, mutect2, varscan2
- PCDHB4 | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV52020403; called by muse, mutect2, varscan2
- PLEKHA4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV99612891; called by muse, mutect2, varscan2
- PTBP2 | c.1355C>T p.S452F (on ENST00000426398 / NM_001300986.2; = p.S444F on NM_021190.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV64623694; called by muse, mutect2
- RRP15 | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV65117502; called by muse, mutect2, varscan2
- RSRC2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs780737907, COSV59203106; called by muse, varscan2
- SLITRK1 | c.2060A>G p.Y687C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV65674719; called by muse, mutect2, varscan2
- ST18 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1384585585, COSV52488016; called by muse, mutect2, varscan2
- TAS2R46 | c.771C>G p.N257K | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs776162761, COSV67853648; called by muse, mutect2, varscan2
- TFAP2D | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV50410524; called by muse, mutect2, varscan2
- TFIP11 | c.1334G>C p.C445S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53225764; called by muse, mutect2, varscan2
- TFR2 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs1246033238, COSV56153433; called by muse, mutect2, varscan2
- TUBA3D | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV58311158; called by muse, mutect2, varscan2
- ZNF248 | c.1559A>G p.Y520C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1271193357, COSV100627672, COSV61997353; called by muse, mutect2, varscan2
- CDH19 | c.1412dup p.Q472Sfs*4 | Frame Shift Ins (INS) | VAF 22/108 reads (20%) | called by mutect2, pindel, varscan2
- LDOC1 | c.144_150del p.S48Rfs*28 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- PCDH11X | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.364); called by mutect2, varscan2
- AIRE | c.393G>A p.K131= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52393051; called by muse, mutect2, varscan2
- DTX1 | c.288C>T p.F96= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1307204382, COSV57496170; called by muse, mutect2, varscan2
- KCNC2 | c.1116A>T p.G372= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54364975; called by mutect2, varscan2
- LEMD3 | c.1080C>T p.N360= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV57649057; called by mutect2, varscan2
- MAGEB3 | c.126C>T p.S42= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs372226669, COSV64396842; called by muse, mutect2, varscan2
- ROR2 | c.1872C>T p.Y624= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs780638428, COSV65217459; called by mutect2, varscan2
- KCTD7 | c.*2C>T | 3'UTR (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51876511; called by muse, mutect2, varscan2
